Surgical pathology report (de-identified scan), TCGA case TCGA-44-A47F, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-A47F-01A (Primary Tumor).

[page 1 of 2]
1C003

Adenocarcinoma, NOS

814013

Site: lung, upper lobe

9-5-12

RD

C34.1

Final Surgical Pathology Report

Procedure:

Diagnosis

A. Lymph node, level X, excision:

Two lymph nodes negative for metastatic carcinoma (0/2).
Vessel negative for tumor.

B. Lung, left upper lobe, excision:

Invasive moderately differentiated adenocarcinoma (see microscopic description).

The tumor measures 5.5 cm in dimension.

Two of 8 hilar lymph nodes positive for metastatic carcinoma (2/8).

C. Lymph node, level VII, excision:

One lymph node negative for metastatic carcinoma (0/1).

D. Lymph node, level V, excision:

One lymph node negative for metastatic carcinoma (0/1).

Microscopic Description:

Histologic type: Adenocarcinoma

Histologic grade: Moderately differentiated

Primary tumor (pT): Tumor measures 5.5 cm in dimension and is organ confined, pT2b

Margins of resection: Tumor is present approximately 4 mm from the bronchial margin. The vascular margin is negative.

Direct extension of tumor: Tumor shows minimal extension into the pleura.

Vessel invasion: Present in a large vessel

Regional lymph nodes (pN): 2 hilar lymph nodes are positive for carcinoma with one showing probable direct extension and the other showing metastatic tumor, the remaining lymph nodes are negative, pN1

Distant metastasis (pM): pMX

Other findings: Dr. has reviewed this case.

Specimen

- A. Level X
- B. Left upper lobe
- C. Level VII
- D. Level V

Clinical Information

Lung cancer

Gross Description

A. Received fresh labeled "level X" are 2 soft gray-black tissues in keeping with lymph nodes averaging 1.3 cm in greatest dimension. Also received within the specimen container is a 1.1 x 0.4 x 0.15 cm fragment of soft tan-pink tissue in keeping with vessel which has several associated staples. RS 2

Summary: 1 - 2 lymph nodes in toto, 2 - possible vascular tissue

B. Received fresh labeled "left upper lobe" is a 233 g, 18.5 x 11.0 x 3.8 cm lobectomy specimen with attached 1 cm in length, 3.5 x 1.0 cm in diameter bronchial stump. The pleura is tan-pink-red with a focal area

[page 2 of 2]
of retraction, subsequently inked blue. An indurated focus is present subjacent to the area of retraction. On sectioning, there is a moderately well-circumscribed, 5.5 x 4.2 x 3.8 cm tan-white tumor mass extends to within 0.1 cm of the inked pleural surface. The tumor extends to the vicinity of the hilum and appears to be within the proximal bronchial stump (to within approximately 0.8 cm of the true bronchial stump margin, see block 5). A portion of tumor and a portion of normal parenchyma are submitted for tissue procurement as requested.

The parenchyma throughout the remainder of the specimen is spongiform tan-pink to tan red. No additional mass lesion or abnormality is noted. Several soft gray-black tissues in keeping with lymph nodes measuring up to 1.3 cm in greatest dimension are recovered from the vicinity of the hilum. RS 10

Summary: 1 - bronchial stump margin, 3 - vascular margins, 2 and 4 - tumor to inked pleural surface, 5 - tumor extending up bronchus (following initial removal of bronchial stump margin), 6 - tumor to normal, 7 and 8 - random normal, 9 - 6 hilar lymph nodes, 10 - one bisected hilar lymph node

C. Received fresh labeled "level VII" is a 0.5 cm slightly rubbery gray-black tissue in keeping with lymph node with a scant amount of associated adipose tissue. AS1

D. Received fresh labeled "level V" is a 0.6 cm gray-black tissue in keeping with lymph node with a moderate amount of associated tan gold adipose tissue. AS1

Source: NCI Genomic Data Commons file 59ebd752-7a35-40e3-ba68-2376559e70e3 (TCGA-44-A47F.FC0E596B-733C-4532-AF0D-94B4A4ECB90C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).